FM case AD6290 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/9031a6d3-fca4-48b6-a07e-893a07799d89

Male, 71.8 years: Acinar cell tumor (ICD-O-3 8550/1) of the major salivary gland; primary biopsied or resected from the parotid gland. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
